Somatic mutation profile of tumor specimen C3N-01879-01 (aliquot CPT0226860006) from CPTAC case C3N-01879, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 67.2 years (24,542 days).
Specimen C3N-01879-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f3a4258-db7f-4c7f-a124-db342c4ff4c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01879-31 (Blood Derived Normal), aliquot CPT0226920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36f43958-6794-4a65-9f95-f1a4bea48533

The open-access MAF lists 2,944 somatic variants for this specimen: 2,063 protein-altering or splice-affecting, 543 silent, 338 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,776, Silent 543, Nonsense Mutation 222, Intron 188, RNA 59, 3'UTR 47, Splice Site 30, Splice Region 19, 5'UTR 17, 5'Flank 15, Frame Shift Ins 12, 3'Flank 12.

Variants (750 of 2,944; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 156/549 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121912678, CM061633, COSV55115924; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 124/496 reads (25%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DCX | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 91/332 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs587783535, CM131050, COSV57570498; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAQ | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 79/275 reads (29%) | hotspot (GDC flag); catalogued as COSV54106777, COSV99680195; called by muse, mutect2, varscan2
- KMT2A | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 81/293 reads (28%) | catalogued as rs727503777, CM150966, COSV63281970; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 76/302 reads (25%) | hotspot (GDC flag); catalogued as COSV54948051; called by mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 109/365 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 96/377 reads (25%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NGLY1 | c.1231C>T p.R411* | Nonsense Mutation (SNP) | VAF 44/166 reads (27%) | catalogued as rs146140738, COSV54984601; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 26/89 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>C p.V411L | Missense Mutation (SNP) | VAF 70/224 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57676103, COSV57677068, COSV57683938; called by muse, mutect2, varscan2
- PTEN | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554893792, COSV64290842, COSV64296487, COSV64301821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 70/332 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SYNJ1 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 68/243 reads (28%) | catalogued as rs1569075471, COSV59145375; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TFG | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 48/180 reads (27%) | catalogued as rs764959531, COSV53749011; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 237/925 reads (26%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTPA | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 125/402 reads (31%) | catalogued as rs121917851, CM981965, COSV52648579; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs753857154, COSV59389120, COSV59390257; called by muse, mutect2, varscan2
- ABCA10 | c.3727G>A p.A1243T | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52228354; called by muse, mutect2, varscan2
- ABCA12 | c.1211G>A p.R404Q (on ENST00000272895 / NM_173076.3; = p.R86Q on NM_015657.3) | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs752328328, COSV55961290, COSV99789386; called by muse, mutect2, varscan2
- ABCA5 | c.4427G>A p.R1476Q | Missense Mutation (SNP) | VAF 71/270 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs750426352, COSV67015792; called by muse, mutect2, varscan2
- ABCA6 | c.2650G>A p.D884N | Missense Mutation (SNP) | VAF 43/230 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs745713208, COSV52636883; called by muse, mutect2, varscan2
- ABCB11 | c.3305C>T p.S1102L | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs762737233; called by muse, mutect2, varscan2
- ABCB5 | c.1760G>A p.R587Q (on ENST00000404938 / NM_001163941.2; = p.R142Q on NM_178559.6) | Missense Mutation (SNP) | VAF 68/234 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs755832012, COSV51702431; called by muse, mutect2, varscan2
- ABCC8 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 148/492 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs577545383, COSV56849292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as rs781206225, COSV53987558; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD1 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as CD106577, COSV54383981, COSV54384712; called by muse, mutect2, varscan2
- ABCD3 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 24/390 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV100239090; called by muse, mutect2
- ABL2 | c.2050G>A p.E684K (on ENST00000502732 / NM_007314.4; = p.E669K on NM_005158.5) | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV61012829; called by muse, mutect2, varscan2
- AC004922.1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs145131136; called by muse, mutect2, varscan2
- AC007040.2 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 92/415 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs140118400; called by muse, mutect2, varscan2
- AC092143.1 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 95/333 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV59248071; called by muse, mutect2, varscan2
- ACACA | c.4187G>A p.R1396Q | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1484000480; called by muse, mutect2, varscan2
- ACACA | c.2375G>A p.R792H | Missense Mutation (SNP) | VAF 78/523 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1213762568; called by muse, mutect2, varscan2
- ACOX2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs1311486181; called by muse, mutect2, varscan2
- ACP3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781475900, COSV60485052; called by muse, mutect2, varscan2
- ACSL4 | c.1915A>G p.I639V (on ENST00000340800 / NM_022977.2; = p.I598V on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/274 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs1395230892; called by muse, mutect2, varscan2
- ACSM2B | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 95/347 reads (27%) | catalogued as rs201804117; called by muse, mutect2, varscan2
- ACSS2 | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766341618, COSV53627576; called by muse, mutect2, varscan2
- ACTN3 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 96/422 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138699570; called by muse, mutect2, varscan2
- ADAMTS2 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 141/583 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.041); catalogued as rs777314559, COSV52364820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2560C>T p.R854W | Missense Mutation (SNP) | VAF 126/482 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs751167134, COSV54439652; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4516C>T p.R1506W | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs781474522; called by muse, mutect2, varscan2
- ADD1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104392570; called by muse, mutect2, varscan2
- ADD2 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 109/413 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs782468498; called by muse, mutect2, varscan2
- ADGB | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV58857360; called by muse, mutect2, varscan2
- ADGRA2 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 89/301 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs147459946, COSV100178112; called by muse, mutect2, varscan2
- ADGRB1 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 90/384 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759102681; called by muse, mutect2, varscan2
- ADGRB2 | c.4496G>A p.R1499H (on ENST00000373658 / NM_001364857.2; = p.R1498H on NM_001294335.2) | Missense Mutation (SNP) | VAF 121/439 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs749337394, COSV57073407; called by muse, mutect2, varscan2
- ADGRB3 | c.1833C>A p.F611L | Missense Mutation (SNP) | VAF 78/266 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.437); catalogued as COSV65383768; called by muse, mutect2, varscan2
- ADGRF2 | c.835G>T p.D279Y (on ENST00000296862 / NM_001368115.2; = p.D211Y on NM_153839.7) | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV99731752; called by muse, mutect2, varscan2
- ADGRL2 | c.2673C>A p.F891L (on ENST00000370717 / NM_001366005.1; = p.F878L on NM_012302.4) | Missense Mutation (SNP) | VAF 98/319 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV54692697; called by muse, mutect2, varscan2
- ADGRV1 | c.4309G>A p.E1437K | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs762744741, COSV67980221; called by muse, mutect2, varscan2
- ADGRV1 | c.14004C>A p.F4668L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV67997246; called by mutect2, varscan2
- ADNP2 | c.31A>G p.N11D | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as rs1325470116; called by muse, varscan2
- AGBL4 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748307842, COSV61891203; called by muse, mutect2, varscan2
- AGK | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780744663, COSV62594437; called by muse, mutect2, varscan2
- AGTR1 | c.750C>A p.F250L | Missense Mutation (SNP) | VAF 75/351 reads (21%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.557); catalogued as COSV62557130, COSV62557404; called by muse, mutect2, varscan2
- AKAP9 | c.5935C>T p.R1979C (on ENST00000359028; = p.R1947C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/443 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV62337737; called by muse, mutect2, varscan2
- AKNA | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56311571; called by muse, mutect2, varscan2
- AKR1D1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 133/465 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs779758762, COSV54339065; called by muse, mutect2, varscan2
- AKR7L | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as rs1344870208; called by muse, mutect2, varscan2
- AL645922.1 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 126/442 reads (29%) | catalogued as COSV100191455; called by muse, varscan2
- ALCAM | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV60246086; called by muse, mutect2, varscan2
- ALDH1L2 | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs778654002, COSV51554714; called by muse, mutect2, varscan2
- ALG6 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 149/506 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746339839, COSV54765958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALK | c.4390C>T p.R1464* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as rs374135358, COSV101201808; called by muse, mutect2, varscan2
- ALKBH6 | c.119G>A p.R40Q (on ENST00000252984 / NM_001297701.2; = p.R68Q on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.041); catalogued as rs201735546, COSV53324572; called by muse, mutect2, varscan2
- ALMS1 | c.11032C>T p.R3678W | Missense Mutation (SNP) | VAF 86/314 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs766771102, COSV52509094; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALX1 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 63/228 reads (28%) | catalogued as rs150997122, COSV57492012; called by muse, mutect2, varscan2
- AMPD3 | c.2188C>T p.R730* (on ENST00000396553 / NM_001025389.2; = p.R739* on NM_000480.3) | Nonsense Mutation (SNP) | VAF 83/399 reads (21%) | catalogued as rs755071594, COSV67330872; called by muse, mutect2, varscan2
- AMY2A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 243/1253 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs750768619, COSV70215035; called by muse, mutect2, varscan2
- ANAPC5 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 51/216 reads (24%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.985); catalogued as rs782244195, COSV99945935; called by muse, mutect2, varscan2
- ANK2 | c.10804C>T p.R3602* | Nonsense Mutation (SNP) | VAF 20/458 reads (4%) | catalogued as COSV52152721; called by muse, mutect2
- ANK2 | c.11134G>A p.V3712I | Missense Mutation (SNP) | VAF 151/541 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs146476345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD12 | c.2360C>A p.S787Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.054); catalogued as COSV50847396; called by muse, mutect2, varscan2
- ANKRD12 | c.4715C>T p.A1572V | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs374059491; called by muse, mutect2, varscan2
- ANKRD30A | c.1534G>T p.E512* (on ENST00000611781; = p.E456* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 21/86 reads (24%) | catalogued as COSV64619201; called by muse, mutect2, varscan2
- ANO2 | c.2967G>T p.M989I (on ENST00000356134 / NM_001278597.3; = p.M993I on NM_001278596.3) | Missense Mutation (SNP) | VAF 101/358 reads (28%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV59034349; called by muse, mutect2, varscan2
- ANOS1 | c.1656G>T p.E552D | Missense Mutation (SNP) | VAF 150/536 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV99391354; called by muse, mutect2, varscan2
- ANXA11 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 149/570 reads (26%) | catalogued as rs372305403, COSV55417806; called by muse, mutect2, varscan2
- ANXA8L1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 61/116 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs782517105; called by muse, mutect2, varscan2
- AP1G1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 107/431 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55485296; called by muse, mutect2, varscan2
- AP3B1 | c.2404G>T p.E802* | Nonsense Mutation (SNP) | VAF 38/150 reads (25%) | catalogued as COSV54876236; called by muse, mutect2, varscan2
- AP3B1 | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 132/482 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748191084, COSV54877031; called by muse, mutect2, varscan2
- APBA2 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 210/780 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67105725; called by muse, mutect2, varscan2
- APBB2 | c.2158C>T p.R720* (on ENST00000295974 / NM_001166050.2; = p.R721* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 118/444 reads (27%) | catalogued as rs1560589921, COSV55948589; called by muse, mutect2, varscan2
- APC | c.7880C>A p.S2627Y | Missense Mutation (SNP) | VAF 62/224 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV57362503; called by muse, mutect2, varscan2
- APOB | c.4883C>T p.A1628V | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); catalogued as COSV51934043; called by muse, mutect2, varscan2
- APOBEC3B | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs781250164; called by muse, mutect2, varscan2
- AQP9 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs752717219, COSV99583139; called by muse, mutect2, varscan2
- ARHGAP22 | c.1031A>C p.K344T | Missense Mutation (SNP) | VAF 135/468 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV50949459; called by muse, mutect2, varscan2
- ARHGAP29 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53110295, COSV99558207; called by muse, mutect2, varscan2
- ARHGAP31 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 88/367 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV51790087; called by muse, mutect2, varscan2
- ARHGAP5 | c.3364C>T p.R1122* | Nonsense Mutation (SNP) | VAF 49/141 reads (35%) | catalogued as COSV61534005; called by muse, mutect2, varscan2
- ARHGEF18 | c.2833G>A p.V945M (on ENST00000359920 / NM_001130955.2; = p.V841M on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/483 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as rs754464153; called by muse, mutect2, varscan2
- ARHGEF6 | c.2293C>T p.R765* | Nonsense Mutation (SNP) | VAF 154/536 reads (29%) | catalogued as rs952314313, COSV51691658; called by muse, mutect2, varscan2
- ARID2 | c.3722A>C p.K1241T | Missense Mutation (SNP) | VAF 91/382 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100536554; called by muse, mutect2, varscan2
- ARL8B | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs766948599, COSV56577028; called by muse, mutect2, varscan2
- ARMC4 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 150/520 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs773935799, COSV59466357, COSV59472634; called by muse, mutect2, varscan2
- ARSI | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.142); catalogued as rs142267983; called by muse, mutect2, varscan2
- ART4 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as rs775874295, COSV57452297, COSV99966843; called by muse, mutect2, varscan2
- ASB15 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 82/258 reads (32%) | catalogued as rs1237485684, COSV51923543; called by muse, mutect2, varscan2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 86/272 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2, varscan2
- ASH1L | c.6232C>T p.R2078C (on ENST00000368346 / NM_001366177.2; = p.R2073C on NM_018489.3) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs772388982, COSV64204956; called by muse, mutect2, varscan2
- ASPM | c.306G>T p.E102D | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs777019490; called by muse, mutect2, varscan2
- ASXL3 | c.1154C>A p.S385Y | Missense Mutation (SNP) | VAF 84/241 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV52461178; called by muse, mutect2, varscan2
- ATG4C | c.802A>G p.N268D | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as rs754157177; called by muse, mutect2, varscan2
- ATP1A3 | c.365C>T p.A122V (on ENST00000545399 / NM_001256214.2; = p.A109V on NM_152296.5) | Missense Mutation (SNP) | VAF 199/718 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1568866568, COSV57486973; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2B1 | c.3373C>T p.R1125C | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53804270; called by muse, mutect2, varscan2
- ATP4A | c.1948G>A p.E650K | Missense Mutation (SNP) | VAF 50/207 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as rs779455265, COSV52870058; called by muse, mutect2, varscan2
- ATP6V1D | c.108dup p.S37Ifs*2 | Frame Shift Ins (INS) | VAF 50/262 reads (19%) | catalogued as rs1281954651; called by mutect2, pindel, varscan2
- ATP7A | c.2944G>T p.E982* | Nonsense Mutation (SNP) | VAF 67/288 reads (23%) | catalogued as CM110857, COSV58443017; called by muse, mutect2, varscan2
- ATRX | c.1493G>T p.R498I | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as COSV64875685; called by muse, mutect2, varscan2
- AUTS2 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 148/518 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100716898; called by muse, mutect2, varscan2
- B3GNT7 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 145/551 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs375567551, COSV55005744; called by muse, mutect2, varscan2
- B4GALNT1 | c.1389C>A p.F463L | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100247035; called by muse, mutect2, varscan2
- BAG6 | c.3275G>A p.R1092H (on ENST00000676571; = p.R1045H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 69/244 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99277058; called by muse, mutect2, varscan2
- BATF3 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 97/362 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767493633; called by muse, mutect2, varscan2
- BBS9 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs899716022, COSV54157337; called by muse, mutect2, varscan2
- BBX | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs770429733, COSV57888159; called by muse, mutect2, varscan2
- BCAS2 | c.296A>T p.D99V | Missense Mutation (SNP) | VAF 69/276 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV65767359; called by muse, mutect2, varscan2
- BCHE | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 52/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745482371, COSV52262810; called by muse, mutect2, varscan2
- BCLAF1 | c.1449A>C p.K483N | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV62144090; called by muse, mutect2
- BCS1L | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 229/811 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55306711; called by muse, mutect2, varscan2
- BDP1 | c.1019A>C p.K340T | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62430717; called by muse, mutect2, varscan2
- BFAR | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs867098456; called by muse, mutect2, varscan2
- BFSP1 | c.535-1G>T p.X179_splice | Splice Site (SNP) | VAF 40/158 reads (25%) | catalogued as COSV64899915; called by muse, mutect2, varscan2
- BFSP2 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 88/354 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs200369728; called by muse, mutect2, varscan2
- BIRC6 | c.6317C>T p.S2106L | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs148607215; called by muse, mutect2, varscan2
- BLVRA | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 140/492 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs746796433, COSV99645997; called by muse, mutect2, varscan2
- BNC2 | c.1300T>C p.S434P | Missense Mutation (SNP) | VAF 131/442 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.348); catalogued as rs1392982973; called by muse, mutect2, varscan2
- BNIP5 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 157/645 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs151027628; called by muse, mutect2, varscan2
- BOD1L1 | c.3664G>T p.E1222* | Nonsense Mutation (SNP) | VAF 51/153 reads (33%) | catalogued as COSV50010055; called by muse, mutect2, varscan2
- BOLA1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 96/341 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs782290172; called by muse, mutect2, varscan2
- BRCA2 | c.4416G>T p.K1472N | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.335); catalogued as CD1413428, COSV66451612; called by muse, mutect2, varscan2
- BRINP1 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 91/302 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs1453440054, COSV99775127; called by muse, mutect2, varscan2
- BRS3 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | catalogued as COSV65710876; called by muse, varscan2
- BRWD1 | c.5526G>T p.M1842I | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV60894376; called by muse, mutect2, varscan2
- BSN | c.7165C>T p.R2389W | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776078996; called by muse, mutect2, varscan2
- C10orf120 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1431253930, COSV61491778, COSV61492642; called by muse, mutect2, varscan2
- C10orf90 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 123/448 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV99504962; called by muse, mutect2, varscan2
- C18orf54 | c.17C>G p.T6R | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.118); catalogued as rs762510584; called by muse, mutect2, varscan2
- C1QB | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 99/351 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.194); catalogued as COSV59244955; called by muse, mutect2, varscan2
- C2CD5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 139/500 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1358127069, COSV61724153; called by muse, mutect2, varscan2
- C2orf16 | c.4357C>T p.R1453* | Nonsense Mutation (SNP) | VAF 112/364 reads (31%) | catalogued as rs557771429, COSV62673324; called by muse, mutect2, varscan2
- C3AR1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 66/235 reads (28%) | catalogued as COSV50817637; called by muse, mutect2, varscan2
- C4orf54 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 69/312 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); catalogued as rs546945111; called by muse, mutect2, varscan2
- C9orf85 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as rs147625713; called by muse, mutect2, varscan2
- CA3 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 117/453 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs773052803, COSV99570671; called by muse, mutect2, varscan2
- CACFD1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 14/444 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs146555731; called by muse, mutect2
- CACNA1D | c.6082G>A p.E2028K (on ENST00000350061 / NM_001128840.3; = p.E2048K on NM_000720.4) | Missense Mutation (SNP) | VAF 107/370 reads (29%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.03); catalogued as rs771286149, COSV55443014; called by muse, mutect2, varscan2
- CACNA1E | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as rs1558147711, COSV100703224; called by muse, mutect2, varscan2
- CACNA1E | c.2234C>T p.S745L | Missense Mutation (SNP) | VAF 76/248 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.086); catalogued as rs776757923, COSV62406537; called by muse, mutect2, varscan2
- CACNA1E | c.6073C>T p.R2025W (on ENST00000367573 / NM_001205293.3; = p.R1982W on NM_000721.4) | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs541743081, COSV62386040, COSV62386098; called by muse, mutect2, varscan2
- CACNA1F | c.5645G>A p.G1882E | Missense Mutation (SNP) | VAF 96/354 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.454); catalogued as COSV59904513; called by muse, mutect2, varscan2
- CACNA1H | c.6031C>T p.R2011W | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs753241781, COSV99326742; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG7 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99711884; called by muse, mutect2, varscan2
- CALML4 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61206027; called by muse, mutect2, varscan2
- CALR3 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 165/648 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1212903941; called by muse, mutect2, varscan2
- CAMK1D | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as rs762894114; called by muse, mutect2, varscan2
- CAPN12 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370271870; called by muse, mutect2, varscan2
- CARMIL1 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as rs558045301, COSV61515810; called by muse, mutect2, varscan2
- CASP1 | c.514G>T p.E172* (on ENST00000436863 / NM_033292.4; = p.E151* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 56/181 reads (31%) | catalogued as rs768953462; called by muse, varscan2
- CASP8 | c.203G>A p.R68Q | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.26); catalogued as rs1339962485, COSV51846409, COSV51847390, COSV51855757; called by muse, mutect2, varscan2
- CC2D2B | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 69/315 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373755580; called by muse, mutect2, varscan2
- CCAR1 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56268629; called by mutect2, varscan2
- CCBE1 | c.244C>A p.L82I | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV101232786; called by muse, mutect2, varscan2
- CCDC110 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs546423737, COSV56873334; called by muse, mutect2
- CCDC125 | c.559G>T p.E187* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as COSV67287673; called by muse, mutect2, varscan2
- CCDC15 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.373); catalogued as rs201773360; called by muse, mutect2
- CCDC157 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 165/595 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs140264936; called by muse, mutect2, varscan2
- CCDC168 | c.15393G>T p.K5131N | Missense Mutation (SNP) | VAF 73/258 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.324); catalogued as COSV59422092; called by muse, mutect2, varscan2
- CCDC175 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs188044309, COSV99877666; called by muse, mutect2, varscan2
- CCDC190 | c.210C>A p.F70L | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as COSV63362841; called by muse, mutect2, varscan2
- CCDC25 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 104/380 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs374219944; called by muse, mutect2, varscan2
- CCDC7 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 61/225 reads (27%) | catalogued as COSV53226367; called by muse, mutect2, varscan2
- CCDC80 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 132/478 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774845090, COSV99245016; called by muse, mutect2, varscan2
- CCDC87 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1357619729, COSV104402656; called by muse, mutect2, varscan2
- CCDC90B | c.697C>A p.R233S | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs148744063, COSV52623726; called by muse, mutect2, varscan2
- CCL16 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs199602184; called by muse, mutect2, varscan2
- CCNB3 | c.1773G>T p.K591N | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1200046820, COSV99328390; called by muse, mutect2, varscan2
- CCNL2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 68/269 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68766626; called by muse, mutect2, varscan2
- CCNO | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 130/449 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs1306714783; called by muse, mutect2, varscan2
- CCNT2 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 28/129 reads (22%) | catalogued as COSV51472643; called by muse, mutect2, varscan2
- CCR2 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs934480642, COSV52747642; called by muse, mutect2, varscan2
- CCSER1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 99/377 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1362443481, COSV61452464; called by muse, mutect2, varscan2
- CCT6B | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as rs1244990017, COSV100030461; called by muse, mutect2, varscan2
- CD163 | c.624C>A p.F208L | Missense Mutation (SNP) | VAF 92/388 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.479); catalogued as COSV63132019; called by muse, mutect2, varscan2
- CD163L1 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV58010812; called by muse, mutect2
- CD200R1 | c.202A>C p.N68H (on ENST00000471858 / NM_170780.3; = p.N91H on NM_138806.4) | Missense Mutation (SNP) | VAF 64/202 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.48); catalogued as COSV55599231; called by muse, mutect2, varscan2
- CD79B | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 197/780 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs778771873, COSV50077885, COSV99137757; called by muse, mutect2, varscan2
- CDC27 | c.1544A>G p.Y515C | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50368470; called by muse, mutect2, varscan2
- CDH10 | c.1657G>T p.G553* | Nonsense Mutation (SNP) | VAF 42/241 reads (17%) | catalogued as rs770340870, COSV52584569; called by muse, mutect2, varscan2
- CDH20 | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs753375305, COSV53019864; called by muse, mutect2, varscan2
- CDH5 | c.460C>T p.R154W | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs565746566; called by muse, mutect2, varscan2
- CDH7 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100542515, COSV59890864; called by muse, mutect2
- CDK1 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 66/292 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1312102931, COSV57349753; called by muse, mutect2, varscan2
- CDK13 | c.3991T>C p.S1331P | Missense Mutation (SNP) | VAF 47/190 reads (25%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1265486026; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3199G>T p.E1067* | Nonsense Mutation (SNP) | VAF 87/331 reads (26%) | catalogued as COSV100575737; called by muse, mutect2, varscan2
- CDKL5 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 204/664 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV66110150; called by muse, mutect2, varscan2
- CDON | c.3238A>G p.T1080A | Missense Mutation (SNP) | VAF 105/331 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs758239580, COSV54996072; called by muse, mutect2, varscan2
- CDSN | c.443C>T p.S148L | Missense Mutation (SNP) | VAF 134/407 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs866521224; called by muse, mutect2, varscan2
- CECR2 | c.1690C>T p.R564W (on ENST00000342247 / NM_001290047.2; = p.R381W on NM_001290046.1) | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1015830181, COSV52837232; called by muse, mutect2, varscan2
- CELA1 | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs376966959; called by muse, mutect2, varscan2
- CENPF | c.3598G>T p.E1200* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100871552, COSV65276017; called by muse, mutect2, varscan2
- CENPN | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs528102999, COSV55141477; called by muse, mutect2, varscan2
- CEP152 | c.1708G>T p.D570Y | Missense Mutation (SNP) | VAF 139/587 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1163254409; called by muse, mutect2, varscan2
- CEP164 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 74/262 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs751931460, COSV54038848; called by muse, mutect2, varscan2
- CEP170 | c.4421C>A p.S1474Y | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV60508818; called by muse, mutect2, varscan2
- CEP192 | c.4301C>A p.A1434D | Missense Mutation (SNP) | VAF 66/252 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV100382437; called by muse, mutect2, varscan2
- CEP295 | c.4961C>T p.S1654L | Missense Mutation (SNP) | VAF 103/386 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as rs1009692028, COSV57353362; called by muse, mutect2, varscan2
- CFAP221 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs552536625, COSV54656355; called by muse, mutect2, varscan2
- CFAP43 | c.4689G>T p.K1563N | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100829210; called by muse, mutect2, varscan2
- CFAP47 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs780374404, COSV52880535, COSV52882723; called by muse, mutect2, varscan2
- CFAP54 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV100127539; called by muse, mutect2, varscan2
- CFAP58 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 87/299 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs746292556, COSV57211513; called by muse, mutect2, varscan2
- CFAP91 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1186370643, COSV56343040; called by muse, mutect2
- CFH | c.2175G>T p.M725I | Missense Mutation (SNP) | VAF 101/377 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV100809851, COSV66407370; called by muse, mutect2, varscan2
- CGNL1 | c.1130G>T p.R377I | Missense Mutation (SNP) | VAF 104/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55566186; called by mutect2, varscan2
- CHD8 | c.2004C>A p.F668L (on ENST00000646647 / NM_001170629.2; = p.F389L on NM_020920.4) | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs1445246220, COSV67869656; called by muse, mutect2, varscan2
- CHM | c.1519C>T p.H507Y | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as rs767295175; called by muse, mutect2, varscan2
- CHRNA2 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 208/796 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.868); catalogued as rs775714882, COSV53559906; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST15 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs375217023; called by muse, mutect2, varscan2
- CHST8 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 111/434 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs200371985, COSV52860943; called by muse, mutect2, varscan2
- CKAP2 | c.865G>T p.E289* (on ENST00000378037 / NM_001098525.2; = p.E288* on NM_018204.5) | Nonsense Mutation (SNP) | VAF 21/162 reads (13%) | catalogued as COSV51621706; called by muse, mutect2, varscan2
- CLCN6 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 86/331 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs773306820; called by muse, mutect2, varscan2
- CLCNKB | c.2022G>T p.K674N | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100989699, COSV65153520; called by muse, mutect2, varscan2
- CLDN1 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 129/433 reads (30%) | catalogued as COSV55043691; called by muse, mutect2, varscan2
- CLDN23 | c.414C>A p.F138L | Missense Mutation (SNP) | VAF 87/278 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as rs1449607215, COSV101093087, COSV67731691; called by muse, mutect2, varscan2
- CLEC4C | c.550A>C p.N184H | Missense Mutation (SNP) | VAF 63/243 reads (26%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.461); catalogued as COSV100665312; called by muse, mutect2, varscan2
- CLMN | c.892A>G p.I298V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100112115; called by muse, varscan2
- CLTC | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 108/495 reads (22%) | catalogued as COSV99291998; called by muse, mutect2, varscan2
- CLTCL1 | c.3877C>T p.R1293C | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs781805918, COSV54238893; called by muse, mutect2, varscan2
- CMTR2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 63/218 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs960907780, COSV57605066; called by muse, mutect2, varscan2
- CMYA5 | c.4052C>T p.S1351F | Missense Mutation (SNP) | VAF 73/225 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV104437430; called by muse, mutect2, varscan2
- CNGA1 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs939558963, COSV62055717; called by muse, mutect2, varscan2
- CNKSR2 | c.2300C>T p.S767F | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1569272271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNPPD1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 78/348 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs773704071, COSV56087303; called by muse, mutect2, varscan2
- CNTN4 | c.1161G>T p.E387D | Missense Mutation (SNP) | VAF 85/283 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV61876952; called by muse, mutect2, varscan2
- CNTN4 | c.2398+5C>T | Splice Region (SNP) | VAF 71/287 reads (25%) | catalogued as rs754421398; called by muse, mutect2, varscan2
- CNTRL | c.4456G>A p.E1486K | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs752652281; called by muse, mutect2, varscan2
- COL11A1 | c.4814G>A p.R1605Q | Missense Mutation (SNP) | VAF 144/479 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs371100196; called by muse, mutect2, varscan2
- COL11A1 | c.3842A>C p.K1281T | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV62176327; called by muse, mutect2, varscan2
- COL14A1 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as rs1279837372; called by muse, mutect2, varscan2
- COL24A1 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65308203; called by muse, mutect2, varscan2
- COL5A1 | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 243/784 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs146716315, COSV100879830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 109/428 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.59); catalogued as rs113538665, COSV55107615; called by muse, mutect2, varscan2
- COL6A3 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 99/354 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.195); catalogued as rs1256603031; called by muse, mutect2, varscan2
- COL6A5 | c.7120C>T p.L2374F (on ENST00000312481; = p.L2370F on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/438 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs964452541; called by muse, mutect2, varscan2
- COL6A6 | c.3365C>T p.A1122V | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT tolerated (0.56); PolyPhen probably damaging (1); catalogued as rs768525819, COSV62032106; called by muse, varscan2
- COL9A3 | c.1604-1G>T p.X535_splice | Splice Site (SNP) | VAF 151/534 reads (28%) | catalogued as COSV58986068; called by muse, mutect2, varscan2
- COMP | c.2126G>A p.S709N | Missense Mutation (SNP) | VAF 157/554 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV55876144; called by muse, mutect2, varscan2
- CORIN | c.1666G>T p.D556Y | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56696566; called by muse, mutect2
- CPEB3 | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 92/346 reads (27%) | catalogued as COSV56454301; called by muse, mutect2, varscan2
- CPED1 | c.889C>A p.P297T | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.71); catalogued as rs897482204; called by muse, varscan2
- CPED1 | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562856331; called by muse, mutect2, varscan2
- CPSF6 | c.304C>A p.H102N | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as COSV57017388; called by muse, mutect2, varscan2
- CPXM2 | c.970A>G p.M324V | Missense Mutation (SNP) | VAF 81/264 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as rs778184898; called by muse, mutect2, varscan2
- CRBN | c.815C>A p.S272Y | Missense Mutation (SNP) | VAF 90/353 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV51640050; called by muse, mutect2, varscan2
- CROCC2 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs772318588; called by muse, mutect2, varscan2
- CROCC2 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1238473919; called by muse, mutect2, varscan2
- CRYBG2 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs756237085; called by muse, mutect2, varscan2
- CSMD3 | c.3578G>A p.R1193Q (on ENST00000297405 / NM_001363185.1; = p.R1089Q on NM_052900.3) | Missense Mutation (SNP) | VAF 133/532 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.764); catalogued as rs1323845975, COSV52111209; called by muse, mutect2, varscan2
- CSMD3 | c.3577C>T p.R1193* (on ENST00000297405 / NM_001363185.1; = p.R1089* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 160/521 reads (31%) | catalogued as COSV52145880, COSV52331660; called by muse, varscan2
- CSMD3 | c.1882G>A p.D628N (on ENST00000297405 / NM_001363185.1; = p.D524N on NM_052900.3) | Missense Mutation (SNP) | VAF 20/460 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV52158599; called by muse, mutect2
- CSNK2A3 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 200/731 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1053426341; called by muse, mutect2, varscan2
- CSPP1 | c.2331G>T p.K777N (on ENST00000676605; = p.K736N on NM_024790.6) | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51583975; called by muse, mutect2, varscan2
- CSRNP3 | c.1504G>A p.V502I | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.042); catalogued as rs1290011348, COSV58776393; called by muse, mutect2, varscan2
- CTHRC1 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.915); catalogued as COSV57716134; called by muse, mutect2, varscan2
- CTNNA3 | c.639G>T p.E213D | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV101044329; called by muse, mutect2, varscan2
- CTNNAL1 | c.301A>C p.N101H | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV104394539; called by muse, mutect2, varscan2
- CUL7 | c.2317C>T p.R773W | Missense Mutation (SNP) | VAF 224/833 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1358890131, COSV99538432; called by muse, mutect2, varscan2
- CXADR | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs756679498; called by muse, mutect2, varscan2
- CYB561D1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs767396445, COSV60206029; called by muse, mutect2, varscan2
- CYLC2 | c.586T>G p.S196A | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV100872528, COSV66339761; called by muse, mutect2, varscan2
- CYP2A6 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 85/358 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs778072113, COSV56535479; called by muse, mutect2, varscan2
- CYP4B1 | c.1485G>T p.K495N | Missense Mutation (SNP) | VAF 82/345 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as rs765791466, COSV54724384; called by muse, mutect2, varscan2
- DACH2 | c.1696C>A p.P566T | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV64166911; called by muse, mutect2, varscan2
- DARS2 | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 66/298 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776515724, COSV53405717; called by muse, mutect2, varscan2
- DCAF1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 26/596 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.467); catalogued as rs983271767, COSV60042763; called by muse, mutect2
- DCC | c.1021T>C p.Y341H | Missense Mutation (SNP) | VAF 136/528 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV59138050; called by muse, varscan2
- DCHS1 | c.8776G>A p.A2926T | Missense Mutation (SNP) | VAF 144/621 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.044); catalogued as rs781474739; called by muse, mutect2, varscan2
- DCHS2 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.699); catalogued as rs1463826913; called by muse, mutect2, varscan2
- DCLK1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 100/354 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55175130; called by muse, mutect2, varscan2
- DCTN1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 121/510 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.885); catalogued as rs764615912, COSV62620987; called by muse, mutect2, varscan2
- DCUN1D1 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV53045486; called by muse, mutect2, varscan2
- DDHD2 | c.2089G>T p.E697* | Nonsense Mutation (SNP) | VAF 61/256 reads (24%) | catalogued as COSV101240544; called by muse, mutect2, varscan2
- DEFB124 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 58/163 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV58343059; called by muse, mutect2
- DENND2B | c.3408G>T p.K1136N | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1019454766; called by muse, mutect2, varscan2
- DENND4B | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs375007291, COSV63411300; called by muse, mutect2, varscan2
- DEUP1 | c.497C>A p.S166Y | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.763); catalogued as rs774395193, COSV53213331; called by muse, mutect2, varscan2
- DGCR8 | c.1345G>T p.D449Y | Missense Mutation (SNP) | VAF 115/442 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV61227063; called by muse, mutect2, varscan2
- DGKG | c.1749C>A p.F583L | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs1012017473, COSV53968685; called by muse, mutect2, varscan2
- DHRS2 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs762976156; called by muse, mutect2, varscan2
- DIAPH1 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 178/715 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1002153995, COSV104389749, COSV99526042; called by muse, mutect2, varscan2
- DIAPH1 | c.2514G>T p.K838N | Missense Mutation (SNP) | VAF 114/361 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs761209182, COSV53883958; called by muse, mutect2, varscan2
- DIAPH3 | c.2482G>A p.E828K (on ENST00000400324 / NM_001042517.2; = p.E565K on NM_030932.3) | Missense Mutation (SNP) | VAF 148/508 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs765318944, COSV57368501; called by muse, mutect2, varscan2
- DIAPH3 | c.1343G>A p.R448Q (on ENST00000400324 / NM_001042517.2; = p.R185Q on NM_030932.3) | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs145827856, COSV57369405; called by muse, mutect2, varscan2
- DIS3L2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 61/425 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs775360586; called by muse, mutect2, varscan2
- DLC1 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs191904737, COSV52328121; called by muse, mutect2, varscan2
- DLG4 | c.938G>A p.R313Q (on ENST00000399506 / NM_001321075.3; = p.R356Q on NM_001365.4) | Missense Mutation (SNP) | VAF 129/439 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs764739020, COSV57238233; called by muse, mutect2, varscan2
- DLL3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 203/657 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770966935, COSV52693963; called by muse, mutect2, varscan2
- DMD | c.6741A>C p.K2247N | Missense Mutation (SNP) | VAF 136/424 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as CD159991, COSV58908961; called by muse, varscan2
- DMD | c.6664G>A p.E2222K | Missense Mutation (SNP) | VAF 98/300 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.111); catalogued as COSV58920359; called by muse, varscan2
- DMGDH | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 242/854 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs1219530360; called by muse, mutect2, varscan2
- DMRTA1 | c.712G>T p.E238* | Nonsense Mutation (SNP) | VAF 34/141 reads (24%) | catalogued as COSV57924585; called by mutect2, varscan2
- DMTF1 | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 55/175 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs753917456; called by muse, mutect2, varscan2
- DMXL2 | c.5534G>A p.R1845Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1429598525, COSV51844369; called by muse, mutect2, varscan2
- DNAAF5 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs373565354; called by muse, mutect2, varscan2
- DNAH10 | c.12772G>A p.D4258N (on ENST00000409039; = p.D4197N on NM_207437.3) | Missense Mutation (SNP) | VAF 66/203 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs373336911; called by muse, mutect2, varscan2
- DNAH2 | c.6772G>A p.E2258K | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs780686310, COSV66726564; called by muse, mutect2, varscan2
- DNAH2 | c.10823G>A p.R3608H | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs149631847; called by muse, mutect2, varscan2
- DNAH3 | c.9871C>T p.R3291W | Missense Mutation (SNP) | VAF 104/382 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772203216, COSV54535961; called by muse, mutect2, varscan2
- DNAH5 | c.13730G>A p.R4577Q | Missense Mutation (SNP) | VAF 114/434 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs759563638, COSV54205926, COSV99447576; called by muse, mutect2, varscan2
- DNAH7 | c.822G>T p.M274I | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV56764153; called by muse, mutect2, varscan2
- DNAJB7 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 37/145 reads (26%) | catalogued as rs200813530, COSV53423723, COSV99344481; called by muse, mutect2, varscan2
- DNAJC13 | c.3626G>A p.R1209H | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201816934, COSV53455853; called by muse, mutect2, varscan2
- DNAJC3 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327043796, COSV65130418; called by muse, mutect2, varscan2
- DNHD1 | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 105/339 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs1033715871, COSV54433417; called by muse, mutect2, varscan2
- DOCK1 | c.1232G>A p.R411Q | Missense Mutation (SNP) | VAF 73/220 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54737181; called by muse, mutect2, varscan2
- DOCK10 | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99287631; called by mutect2, varscan2
- DOCK4 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV70325708; called by muse, mutect2, varscan2
- DOCK9 | c.5984C>T p.A1995V (on ENST00000376460 / NM_001366676.2; = p.A1996V on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs754298254, COSV100240827; called by muse, mutect2, varscan2
- DOCK9 | c.404G>A p.R135Q (on ENST00000376460 / NM_001366676.2; = p.R136Q on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs558868727; called by muse, mutect2, varscan2
- DOP1B | c.6865G>A p.E2289K | Missense Mutation (SNP) | VAF 102/293 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747660734; called by muse, mutect2, varscan2
- DPM1 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 107/312 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as COSV100857722, COSV100857742; called by muse, mutect2, varscan2
- DPP6 | c.2252C>T p.A751V (on ENST00000377770 / NM_001364500.2; = p.A689V on NM_001936.5) | Missense Mutation (SNP) | VAF 148/532 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.67); catalogued as rs370708312; called by muse, mutect2, varscan2
- DPYD | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376073289, CM088361, COSV104426935; called by muse, mutect2, varscan2
- DRD1 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV67104884; called by muse, mutect2, varscan2
- DSCAM | c.2963C>A p.P988H | Missense Mutation (SNP) | VAF 77/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68024867; called by muse, mutect2, varscan2
- DSPP | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 131/478 reads (27%) | catalogued as COSV99216778; called by muse, mutect2, varscan2
- DSPP | c.3679G>A p.D1227N | Missense Mutation (SNP) | VAF 347/1121 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.404); catalogued as rs1272184807, COSV56809213; called by muse, mutect2, varscan2
- DTNA | c.1720C>T p.P574S | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV51993255; called by muse, mutect2, varscan2
- DUS1L | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as rs76779621, COSV100152400; called by muse, mutect2, varscan2
- DUSP4 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774219516, COSV99529841; called by muse, mutect2, varscan2
- DYNC2H1 | c.10729C>T p.R3577* | Nonsense Mutation (SNP) | VAF 42/207 reads (20%) | catalogued as rs373536938; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.4219G>A p.D1407N | Missense Mutation (SNP) | VAF 74/240 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1558619808, COSV50269067, COSV50300200; called by muse, mutect2, varscan2
- EBF2 | c.1687G>T p.G563* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV68779675; called by muse, mutect2, varscan2
- EEF2K | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs761170225, COSV53778914; called by muse, mutect2, varscan2
- EFR3B | c.1411C>T p.R471* | Nonsense Mutation (SNP) | VAF 84/409 reads (21%) | catalogued as rs1254796768, COSV53119392, COSV53123261; called by muse, mutect2, varscan2
- EGLN1 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 32/614 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM163984; called by muse, mutect2
- EGR3 | c.65A>G p.D22G | Missense Mutation (SNP) | VAF 117/393 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs751423090; called by muse, mutect2, varscan2
- EIF2AK3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 114/494 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs766640012, COSV57545364; called by muse, mutect2, varscan2
- EIF3E | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV99623526; called by muse, mutect2
- EIF4G2 | c.2032C>T p.L678F | Missense Mutation (SNP) | VAF 91/348 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1425825818; called by muse, mutect2, varscan2
- EIF4G3 | c.1991G>A p.R664Q | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777228085, COSV51679767, COSV51692966; called by muse, mutect2
- ELFN2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.069); catalogued as rs369242294; called by muse, mutect2, varscan2
- ELL2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550971003, COSV52983480; called by muse, mutect2, varscan2
- ELMO1 | c.728C>A p.T243N | Missense Mutation (SNP) | VAF 46/186 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV60300297; called by muse, mutect2, varscan2
- ELMOD1 | c.432C>A p.F144L | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56190577; called by muse, mutect2, varscan2
- ELMOD2 | c.796T>C p.Y266H | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs1425577436; called by muse, mutect2, varscan2
- ELOA | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.097); catalogued as rs147846325, COSV69311219; called by muse, mutect2, varscan2
- EMX1 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747839664; called by muse, mutect2, varscan2
- EOLA1 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as COSV100828388; called by mutect2, varscan2
- EPB41L4A | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs773872614, COSV54866816; called by muse, mutect2, varscan2
- EPB41L4B | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV65796542, COSV65796820; called by muse, mutect2, varscan2
- EPHA3 | c.2647C>T p.R883W | Missense Mutation (SNP) | VAF 45/148 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs752560194, COSV60705886; called by muse, mutect2, varscan2
- EPHB1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs764139128, COSV67657222, COSV67674992; called by muse, mutect2, varscan2
- EPHB1 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 159/583 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs533462328, COSV67662549; called by muse, mutect2, varscan2
- EPHB4 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62268330; called by muse, mutect2
- EPN2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59060580; called by muse, mutect2, varscan2
- ERBB4 | c.3128C>T p.S1043L | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs754420079, COSV100723016, COSV61505401; called by muse, mutect2, varscan2
- ERBB4 | c.2822A>C p.Q941P | Missense Mutation (SNP) | VAF 116/363 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61522432; called by muse, mutect2, varscan2
- ERCC6L | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1339227994, COSV57819781; called by muse, mutect2, varscan2
- ERCC6L | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as COSV100559321; called by muse, mutect2, varscan2
- ERP44 | c.197C>A p.P66Q | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52431937; called by muse, mutect2, varscan2
- ERVW-1 | c.1264C>T p.R422* | Nonsense Mutation (SNP) | VAF 83/308 reads (27%) | catalogued as rs1478670417, COSV71259576; called by mutect2, varscan2
- ESCO1 | c.1718G>A p.R573Q | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200657231, COSV52517980; called by muse, mutect2, varscan2
- ESX1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.445); catalogued as COSV65424066; called by muse, mutect2, varscan2
- ESYT3 | c.979C>T p.L327F | Missense Mutation (SNP) | VAF 83/368 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100004839; called by muse, mutect2, varscan2
- EVC2 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV60391913; called by muse, mutect2, varscan2
- EVI5 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as rs1306676452; called by muse, mutect2, varscan2
- EXT1 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 122/494 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs146983754; called by muse, mutect2, varscan2
- EYS | c.6096G>T p.K2032N | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.321); catalogued as COSV65485910; called by muse, varscan2
- F11R | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 125/530 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); catalogued as rs751710003, COSV57036596; called by muse, mutect2, varscan2
- FAHD2B | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1426534573, COSV55631488; called by muse, mutect2, varscan2
- FAM126A | c.627-1G>T p.X209_splice | Splice Site (SNP) | VAF 33/180 reads (18%) | catalogued as COSV101327113; called by muse, varscan2
- FAM20C | c.906C>A p.F302L | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs11546478, COSV100570511; called by muse, mutect2, varscan2
- FAM220A | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1156709247, COSV57626647; called by muse, mutect2, varscan2
- FAM47B | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 158/599 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV100264644; called by muse, mutect2, varscan2
- FANCM | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 98/364 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53533217, COSV99360924; called by muse, mutect2, varscan2
- FAR1 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as rs1437945875, COSV61384625; called by muse, mutect2
- FASTKD1 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.083); catalogued as rs751291896, COSV71624185; called by muse, mutect2, varscan2
- FASTKD1 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748808096, COSV70007072; called by muse, mutect2, varscan2
- FAT2 | c.3253G>T p.D1085Y | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs915165920; called by mutect2, varscan2
- FAT3 | c.2575G>T p.D859Y | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53074506; called by muse, mutect2, varscan2
- FAT3 | c.13239C>A p.F4413L | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.269); catalogued as COSV53105922; called by muse, mutect2, varscan2
- FAT4 | c.5443C>T p.R1815C | Missense Mutation (SNP) | VAF 126/470 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766427266, COSV58670665; called by muse, mutect2, varscan2
- FBXO32 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 47/199 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV54890529; called by muse, mutect2, varscan2
- FBXO40 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.121); catalogued as rs777614025; called by muse, mutect2, varscan2
- FBXW7 | c.1694T>C p.V565A (on ENST00000281708 / NM_001349798.2; = p.V485A on NM_018315.5) | Missense Mutation (SNP) | VAF 104/400 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55961944; called by muse, mutect2, varscan2
- FCF1 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 28/142 reads (20%) | catalogued as rs1487547933, COSV62043917, COSV62044610; called by muse, mutect2, varscan2
- FCRL2 | c.1415T>C p.V472A | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.184); catalogued as rs1373418162; called by muse, mutect2, varscan2
- FER1L6 | c.3341C>T p.S1114L | Missense Mutation (SNP) | VAF 66/304 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs182459401, COSV67548824; called by muse, mutect2
- FGB | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 71/254 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as CM860027; called by muse, mutect2, varscan2
- FGF14 | c.302C>A p.S101Y | Missense Mutation (SNP) | VAF 19/615 reads (3%) | SIFT tolerated (0.88); PolyPhen benign (0.006); catalogued as COSV65940105, COSV65943955; called by muse, mutect2
- FGF8 | c.200G>A p.R67H (on ENST00000344255 / NM_033164.4; = p.R49H on NM_006119.6) | Missense Mutation (SNP) | VAF 24/644 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1204612800; called by muse, mutect2
- FLG2 | c.4337C>T p.T1446I | Missense Mutation (SNP) | VAF 252/889 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1015695920; called by muse, mutect2, varscan2
- FMO3 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 114/359 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs775749562, CM129718, COSV63007211; called by muse, mutect2, varscan2
- FNDC1 | c.4561G>A p.D1521N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs751784115, COSV51937220; called by muse, mutect2, varscan2
- FOSB | c.472C>T p.R158* | Nonsense Mutation (SNP) | VAF 81/280 reads (29%) | catalogued as COSV62278921; called by muse, mutect2, varscan2
- FOXC2 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 248/871 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100234095; called by muse, mutect2, varscan2
- FOXO1 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 83/299 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65425534; called by muse, mutect2, varscan2
- FOXS1 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 90/398 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs773930926, COSV54065263; called by muse, mutect2, varscan2
- FREM3 | c.4739C>T p.P1580L | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1344010424, COSV100317935; called by muse, mutect2, varscan2
- FRY | c.2414C>T p.S805L | Missense Mutation (SNP) | VAF 94/378 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs200692607, COSV66568144; called by muse, mutect2, varscan2
- FSCN3 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 57/203 reads (28%) | catalogued as rs755925777, COSV50002450; called by muse, mutect2, varscan2
- FSHR | c.1900C>T p.R634C | Missense Mutation (SNP) | VAF 184/684 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769165783, COSV58620040; called by muse, mutect2, varscan2
- FSIP2 | c.19312G>A p.E6438K | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.713); catalogued as COSV58086972, COSV58104330; called by muse, mutect2, varscan2
- FUT9 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV100134322, COSV56143911; called by mutect2, varscan2
- GALC | c.622-1G>T p.X208_splice | Splice Site (SNP) | VAF 64/268 reads (24%) | catalogued as CS971740; called by muse, mutect2, varscan2
- GALNT2 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 85/311 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as rs749888628, COSV64194472; called by muse, mutect2, varscan2
- GALNT2 | c.1186T>G p.Y396D | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64196715; called by muse, mutect2, varscan2
- GALNT9 | c.1733T>C p.F578S (on ENST00000328957 / NM_001122636.2; = p.F212S on NM_021808.3) | Missense Mutation (SNP) | VAF 108/424 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs376656126; called by muse, mutect2, varscan2
- GALNTL5 | c.929G>A p.G310E | Missense Mutation (SNP) | VAF 151/520 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67180873; called by muse, mutect2, varscan2
- GBP6 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs751920580; called by muse, mutect2, varscan2
- GGT6 | c.1196C>T p.A399V (on ENST00000574154 / NM_001122890.3; = p.A367V on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/400 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1166522699; called by muse, mutect2, varscan2
- GIPR | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV54424335; called by muse, mutect2, varscan2
- GJB2 | c.281A>G p.H94R | Missense Mutation (SNP) | VAF 137/499 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67010818; called by muse, mutect2, varscan2
- GLB1L3 | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 49/179 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV66283971; called by muse, mutect2, varscan2
- GLOD5 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1557017311, COSV57488756, COSV57490344; called by muse, mutect2, varscan2
- GLT8D2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 30/160 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as rs775838336, COSV62561704; called by muse, mutect2, varscan2
- GNAI1 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 67/289 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs772844909, COSV100650494; called by muse, mutect2, varscan2
- GNAI3 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766607222, COSV63984496; called by muse, mutect2, varscan2
- GNAS | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 30/696 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.82); catalogued as rs1453878397, COSV58345055; called by muse, mutect2
- GNL2 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 95/341 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as rs373181030; called by muse, mutect2, varscan2
- GNL3L | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 215/768 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as rs765688092, COSV100328493; called by muse, mutect2, varscan2
- GOLGA5 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 101/359 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs554607146, COSV50832421; called by muse, mutect2, varscan2
- GOLGA5 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774532511, COSV50832463; called by muse, mutect2, varscan2
- GOLGA6C | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as rs1015279167; called by mutect2, varscan2
- GOLGA8G | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 73/211 reads (35%) | catalogued as COSV100284547; called by muse, varscan2
- GPAM | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 124/415 reads (30%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.968); catalogued as rs768046520, COSV62080271; called by muse, mutect2, varscan2
- GPBAR1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 110/361 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.659); catalogued as rs200257647, COSV50306809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPLD1 | c.2468C>A p.S823Y | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV51234166; called by muse, mutect2, varscan2
- GPR25 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 129/393 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1417960492; called by muse, mutect2, varscan2
- GPR63 | c.955C>A p.L319I | Missense Mutation (SNP) | VAF 172/629 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57741131; called by muse, mutect2, varscan2
- GRAMD1C | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as rs374197239; called by muse, varscan2
- GRID2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 73/227 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754110902, COSV56172424; called by muse, mutect2, varscan2
- GRIK4 | c.1378C>T p.R460* | Nonsense Mutation (SNP) | VAF 148/548 reads (27%) | catalogued as rs1377111124, COSV70799410; called by muse, mutect2, varscan2
- GRK3 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs146517167; called by muse, mutect2, varscan2
- GRM4 | c.1011G>T p.K337N | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV65211632; called by muse, mutect2, varscan2
- GRWD1 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1438227348; called by muse, mutect2, varscan2
- GUCY2C | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs769797661, COSV53786630, COSV53797359; called by muse, mutect2, varscan2
- HACD3 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs769410818, COSV99970880; called by muse, mutect2, varscan2
- HAT1 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 28/106 reads (26%) | catalogued as rs376598264; called by muse, mutect2
- HCFC1 | c.5635G>A p.E1879K | Missense Mutation (SNP) | VAF 104/435 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs868959030, COSV60074325; called by muse, mutect2, varscan2
- HCFC2 | c.926dup p.N309Kfs*34 | Frame Shift Ins (INS) | VAF 48/186 reads (26%) | catalogued as rs776023139; called by mutect2, varscan2
- HEATR5B | c.5749C>T p.R1917C | Missense Mutation (SNP) | VAF 68/278 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.761); catalogued as rs752271740, COSV99250505; called by muse, mutect2, varscan2
- HEATR6 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 114/339 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs1330187605, COSV51747013; called by muse, mutect2, varscan2
- HEPH | c.1244A>C p.K415T (on ENST00000343002; = p.K148T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV57966063; called by muse, mutect2, varscan2
- HIKESHI | c.279C>G p.S93R | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.148); catalogued as COSV53574170; called by muse, mutect2
- HMCN1 | c.14749C>T p.R4917C | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777793313, COSV54903401, COSV54909108; called by muse, mutect2, varscan2
- HMG20A | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 96/383 reads (25%) | catalogued as COSV60311261; called by muse, mutect2, varscan2
- HMGXB3 | c.1847G>T p.R616I (on ENST00000613459; = p.R370I on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1293685702, COSV101520272; called by muse, mutect2, varscan2
- HNRNPD | c.621+2T>C p.X207_splice | Splice Site (SNP) | VAF 36/96 reads (38%) | catalogued as COSV100002779; called by muse, mutect2, varscan2
- HNRNPH3 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs761715695, COSV56261462; called by muse, mutect2, varscan2
- HOMER2 | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV58486988; called by muse, mutect2, varscan2
- HOMER3 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs759179202; called by muse, mutect2, varscan2
- HORMAD1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100464412; called by muse, mutect2, varscan2
- HOXA5 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1266154517, COSV56072125; called by muse, mutect2, varscan2
- HOXD11 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50910469; called by muse, mutect2, varscan2
- HOXD4 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 133/524 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as rs765300039, COSV60459492; called by muse, mutect2, varscan2
- HPSE | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 95/364 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60986403; called by muse, mutect2, varscan2
- HRG | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 117/429 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as rs764549526, COSV51644228; called by muse, mutect2, varscan2
- HSPA4 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.342); catalogued as rs773711727; called by muse, mutect2, varscan2
- HSPA9 | c.1882G>A p.E628K | Missense Mutation (SNP) | VAF 198/806 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.021); catalogued as rs566717208; called by muse, mutect2, varscan2
- HSPH1 | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 46/253 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100184889; called by muse, mutect2, varscan2
- HTATSF1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); catalogued as COSV54480906, COSV99511578; called by muse, mutect2, varscan2
- HTR2A | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.42); catalogued as rs1428173433, COSV66326797; called by muse, mutect2, varscan2
- HTR2C | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 86/361 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99350987; called by muse, mutect2, varscan2
- ICE1 | c.3301C>T p.R1101* | Nonsense Mutation (SNP) | VAF 63/235 reads (27%) | catalogued as rs758941095, COSV56832745; called by muse, mutect2, varscan2
- IDO1 | c.816C>A p.C272* | Nonsense Mutation (SNP) | VAF 14/312 reads (4%) | catalogued as COSV53716820; called by muse, mutect2
- IFI44 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 136/551 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs534850430, COSV66074512; called by muse, mutect2, varscan2
- IFNA16 | c.116T>C p.I39T | Missense Mutation (SNP) | VAF 122/425 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101207088; called by muse, mutect2, varscan2
- IFNA2 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV101206969; called by muse, mutect2, varscan2
- IFNA8 | c.167G>T p.R56I | Missense Mutation (SNP) | VAF 146/568 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV66504485; called by muse, mutect2, varscan2
- IFNG | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV57490591, COSV57491133; called by muse, mutect2, varscan2
- IGF1 | c.57C>A p.F19L | Missense Mutation (SNP) | VAF 86/369 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV61032796; called by muse, mutect2, varscan2
- IGLON5 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV54534245; called by muse, mutect2, varscan2
- IL12RB1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 128/496 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.14); catalogued as rs1447702115, COSV74045686; called by muse, varscan2
- IL17RA | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 101/354 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs201500195; called by muse, mutect2, varscan2
- IL17RC | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 182/577 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs1378358931; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1763C>T p.S588L | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.677); catalogued as COSV100148886; called by muse, mutect2, varscan2
- IL6 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV51732665; called by muse, mutect2, varscan2
- IL6ST | c.1353G>T p.K451N | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100411024, COSV61140244; called by muse, mutect2, varscan2
- IL7 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753164075, COSV55676535; called by muse, mutect2, varscan2
- ILK | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 249/955 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1257537906; called by muse, mutect2, varscan2
- ING3 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 52/193 reads (27%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.921); catalogued as rs908317865, COSV59950940; called by muse, mutect2, varscan2
- IQCH | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 58/177 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs746971338, COSV60058642; called by muse, mutect2, varscan2
- IRAG2 | c.3566G>A p.R1189Q (on ENST00000636465; = p.R234Q on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs751560656, COSV63138483; called by muse, mutect2, varscan2
- ITGA8 | c.552C>A p.F184L | Missense Mutation (SNP) | VAF 105/360 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV65226944; called by muse, mutect2, varscan2
- ITGAD | c.2099G>T p.R700I | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV101210500; called by muse, mutect2
- ITGAE | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 36/140 reads (26%) | catalogued as COSV53991968; called by muse, mutect2, varscan2
- ITGB7 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.042); catalogued as COSV57238538, COSV57240555; called by muse, mutect2, varscan2
- ITIH3 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs772751051; called by muse, mutect2, varscan2
- ITPK1 | c.777C>G p.D259E | Missense Mutation (SNP) | VAF 100/347 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.666); catalogued as COSV50893819, COSV99968238; called by muse, mutect2, varscan2
- ITSN1 | c.3008C>T p.S1003L | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs772284990, COSV66084289; called by muse, mutect2, varscan2
- JAG1 | c.1886-1G>A p.X629_splice | Splice Site (SNP) | VAF 116/512 reads (23%) | catalogued as COSV54761389; called by muse, mutect2, varscan2
- JAK1 | c.2530G>T p.D844Y | Missense Mutation (SNP) | VAF 11/327 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61097581; called by muse, mutect2
- JAK2 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 103/360 reads (29%) | catalogued as COSV67589468; called by muse, mutect2, varscan2
- JAK2 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67579253; called by muse, mutect2, varscan2
- JAKMIP2 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs934467542, COSV54599978; called by muse, mutect2, varscan2
- JAM3 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 145/484 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs771822749; called by muse, mutect2, varscan2
- KALRN | c.5285G>A p.R1762H (on ENST00000360013 / NM_001024660.4; = p.R65H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/494 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1232010971, COSV52249060; called by muse, mutect2, varscan2
- KANK3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs62120998; called by muse, mutect2, varscan2
- KANK4 | c.1762G>A p.A588T | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs74424889; called by muse, mutect2, varscan2
- KAT6B | c.3559C>T p.P1187S | Missense Mutation (SNP) | VAF 160/505 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.986); catalogued as rs370725802; called by muse, mutect2, varscan2
- KCNA6 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 146/592 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54974128, COSV99768741; called by muse, mutect2, varscan2
- KCNA7 | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99671802; called by muse, mutect2, varscan2
- KCNG4 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 94/337 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs557936871; called by muse, mutect2, varscan2
- KCNJ8 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 107/436 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV99557341; called by muse, mutect2, varscan2
- KCNMB4 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV50690996; called by muse, mutect2
- KCNN1 | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.146); catalogued as rs1481868375; called by muse, mutect2, varscan2
- KCNS2 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 76/644 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as rs138992941; called by muse, mutect2, varscan2
- KDM4C | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67185398; called by muse, mutect2, varscan2
- KERA | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 93/267 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs148063461; called by muse, mutect2, varscan2
- KIAA1109 | c.4700C>A p.S1567Y | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV52681682; called by muse, mutect2, varscan2
- KIAA1109 | c.10889G>A p.R3630Q | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1019117921, COSV52682924; called by muse, mutect2, varscan2
- KIAA1671 | c.4858G>A p.A1620T | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs998442810; called by muse, mutect2, varscan2
- KIAA2026 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs888005312; called by muse, mutect2, varscan2
- KIAA2026 | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV67356700, COSV67357808; called by muse, mutect2, varscan2
- KIF13B | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs758163466, COSV72879504; called by muse, mutect2, varscan2
- KIF21B | c.2836-1G>T p.X946_splice | Splice Site (SNP) | VAF 32/124 reads (26%) | catalogued as COSV100144773; called by muse, mutect2, varscan2
- KIF26A | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 74/309 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768745005; called by muse, mutect2, varscan2
- KIF3C | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV53100835; called by muse, mutect2, varscan2
- KLC1 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as rs760362554; called by muse, mutect2, varscan2
- KLF12 | c.1189C>T p.R397W | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1257857115; called by muse, mutect2, varscan2
- KLHL10 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.313); catalogued as rs782811323, COSV104394486; called by muse, mutect2, varscan2
- KLHL13 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.063); catalogued as rs758950986, COSV53245230; called by muse, mutect2
- KLHL14 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT tolerated (1); PolyPhen probably damaging (0.979); catalogued as rs1568061832, COSV63833650; called by muse, mutect2, varscan2
- KLHL24 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763228635, COSV54424734; called by muse, mutect2, varscan2
- KLHL28 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1162419619, COSV61888794; called by muse, mutect2, varscan2
- KLK13 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 101/380 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.86); catalogued as rs372211156; called by muse, mutect2, varscan2
- KMT2B | c.7699C>T p.R2567C | Missense Mutation (SNP) | VAF 83/316 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs1393734909, COSV53074326; called by muse, mutect2, varscan2
- KMT2C | c.14078G>A p.R4693Q | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777526116, COSV51286192; called by muse, mutect2, varscan2
- KMT2C | c.8596G>A p.E2866K | Missense Mutation (SNP) | VAF 56/243 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV51423215; called by muse, mutect2, varscan2
- KMT2E | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs541275939, COSV57569382; called by muse, mutect2
- KPNA7 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 181/690 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs1370342038; called by muse, mutect2, varscan2
- KRT222 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 63/222 reads (28%) | catalogued as COSV67499339; called by muse, mutect2, varscan2
- KRT38 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs529308915, COSV55846812, COSV55847380; called by muse, mutect2, varscan2
- KRT4 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 142/527 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as rs748688818; called by muse, mutect2, varscan2
- KRT71 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 74/307 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.341); catalogued as rs1394956135, COSV57289517; called by muse, mutect2, varscan2
- KRTAP12-3 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 147/485 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs782406301, COSV59951981; called by muse, mutect2, varscan2
- KRTAP16-1 | c.1301G>A p.R434H | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); catalogued as rs888227916; called by muse, mutect2, varscan2
- KRTAP24-1 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as rs758473615, COSV61089233, COSV61089290; called by muse, mutect2, varscan2
- L2HGDH | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 53/241 reads (22%) | catalogued as rs547796370, CM087992, COSV55555832, COSV55557458; called by muse, mutect2, varscan2
- LAMA2 | c.6305T>C p.L2102S | Missense Mutation (SNP) | VAF 90/328 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70351412; called by muse, mutect2, varscan2
- LAMA3 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 229/809 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as rs766705233; called by muse, mutect2, varscan2
- LAMB4 | c.4353A>C p.E1451D | Missense Mutation (SNP) | VAF 103/336 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs1448093156; called by muse, mutect2, varscan2
- LARP4B | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs776303473, COSV100295138; called by muse, varscan2
- LARP6 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs778158575, COSV54580631; called by muse, mutect2, varscan2
- LCA5 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 20/225 reads (9%) | catalogued as COSV63971794; called by muse, mutect2
- LCTL | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58422694; called by muse, mutect2, varscan2
- LEAP2 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs771383357, COSV51527893; called by muse, mutect2, varscan2
- LGR4 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775198460, COSV60820564; called by muse, mutect2, varscan2
- LGR6 | c.855G>A p.T285= (on ENST00000367278 / NM_001017403.1; = p.T233= on NM_021636.3) | Splice Region (SNP) | VAF 35/124 reads (28%) | catalogued as rs749687454, COSV55151967, COSV99707686; called by muse, mutect2, varscan2
- LIG3 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 110/443 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs201706144, COSV52010989; called by muse, mutect2, varscan2
- LIG4 | c.877C>T p.R293* | Nonsense Mutation (SNP) | VAF 7/122 reads (6%) | catalogued as rs948441067, COSV100799917; called by muse, mutect2
- LONP2 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs763860627, COSV53520629, COSV99589549; called by muse, mutect2, varscan2
- LOXL2 | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 218/650 reads (34%) | catalogued as rs759081095, COSV66690376; called by muse, mutect2, varscan2
- LPCAT1 | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 133/372 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as rs529710476, COSV99359327; called by muse, mutect2, varscan2
- LPL | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 119/471 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60931920; called by muse, mutect2, varscan2
- LRBA | c.8275G>T p.E2759* | Nonsense Mutation (SNP) | VAF 86/290 reads (30%) | catalogued as COSV63961130; called by muse, mutect2, varscan2
- LRCOL1 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 81/238 reads (34%) | PolyPhen benign (0.015); catalogued as rs777255601; called by muse, mutect2, varscan2
- LRP12 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs779021302, COSV99407504; called by muse, mutect2
- LRP1B | c.1915C>A p.L639I | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV101258243; called by muse, mutect2, varscan2
- LRRC14B | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 79/275 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as rs1028644702, COSV52045226; called by muse, mutect2, varscan2
- LRRC2 | c.-20+8G>A | Splice Region (SNP) | VAF 191/583 reads (33%) | catalogued as rs748154683; called by muse, mutect2, varscan2
- LRRC49 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 66/247 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs199883910, COSV53011514; called by muse, mutect2, varscan2
- LRRK2 | c.2299C>T p.R767C | Missense Mutation (SNP) | VAF 101/348 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs201823680, COSV54148011; called by muse, mutect2, varscan2
- LRRK2 | c.3777+8G>A | Splice Region (SNP) | VAF 32/142 reads (23%) | catalogued as rs201717503; called by muse, mutect2, varscan2
- LRRK2 | c.6544C>A p.L2182I | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100110507, COSV54156156; called by muse, mutect2, varscan2
- LSAMP | c.333C>A p.C111* | Nonsense Mutation (SNP) | VAF 132/506 reads (26%) | catalogued as COSV61278789; called by muse, mutect2, varscan2
- LUZP2 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 69/250 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs543569589, COSV61221699; called by muse, mutect2, varscan2
- LY6L | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs762233937; called by muse, mutect2, varscan2
- LY96 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 42/293 reads (14%) | catalogued as COSV53024608; called by muse, mutect2, varscan2
- LYSMD1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 104/415 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.478); catalogued as rs1331757069; called by muse, mutect2, varscan2
- LZTS2 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs772183641, COSV100932280, COSV64651088; called by muse, mutect2
- MACC1 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 73/290 reads (25%) | catalogued as COSV60541345, COSV60547267; called by muse, mutect2, varscan2
- MACROD2 | c.728-1G>T p.X243_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | catalogued as COSV53945802, COSV53967629, COSV54057646; called by muse, mutect2, varscan2
- MAGEA8 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs782267175, COSV54064067; called by muse, mutect2, varscan2
- MAGED2 | c.1323C>A p.F441L | Missense Mutation (SNP) | VAF 90/377 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as COSV54499496; called by muse, mutect2, varscan2
- MAMLD1 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99475565; called by muse, mutect2, varscan2
- MAN2A2 | c.2290G>A p.A764T | Missense Mutation (SNP) | VAF 142/569 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs768828956, COSV64638165; called by muse, mutect2, varscan2
- MAN2B2 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.073); catalogued as rs372022402; called by muse, mutect2, varscan2
- MAP1B | c.4543G>T p.E1515* | Nonsense Mutation (SNP) | VAF 30/194 reads (15%) | catalogued as COSV57094522, COSV57097012; called by muse, mutect2, varscan2
- MAP2K1 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 165/587 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs1567009054, COSV61069333; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K4 | c.4168G>A p.E1390K | Missense Mutation (SNP) | VAF 59/256 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs967319561, COSV62330502; called by muse, mutect2, varscan2
- MAP3K9 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 86/380 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751015012, COSV67122589; called by muse, mutect2, varscan2
- MAP4K4 | c.2755C>T p.R919C (on ENST00000347699 / NM_001242559.2; = p.R837C on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/252 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs375228116; called by muse, mutect2, varscan2
- MARK3 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 111/373 reads (30%) | catalogued as rs757596077; called by muse, mutect2, varscan2
- MBIP | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749949801; called by muse, mutect2, varscan2
- MBOAT2 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1471364240, COSV60007642; called by muse, mutect2, varscan2
- MCF2 | c.1987G>A p.D663N | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.099); catalogued as rs749558275; called by muse, mutect2, varscan2
- MCF2L2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 80/301 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs983703431, COSV61052860; called by muse, mutect2, varscan2
- MCHR2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs142259467, COSV56001077; called by muse, mutect2, varscan2
- MCM3AP | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 84/278 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs146531143; called by muse, mutect2, varscan2
- MDGA2 | c.1871G>A p.R624Q (on ENST00000399232 / NM_001113498.2; = p.R326Q on NM_182830.4) | Missense Mutation (SNP) | VAF 143/389 reads (37%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.531); catalogued as rs553082374, COSV62105261; called by muse, mutect2, varscan2
- MDN1 | c.14563G>T p.E4855* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as COSV65530281; called by muse, mutect2
- MDN1 | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 58/208 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765830778, COSV65529001; called by muse, mutect2, varscan2
- MECOM | c.1586C>T p.S529L (on ENST00000468789 / NM_001105078.4; = p.S717L on NM_004991.4) | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as rs1169063502, COSV52966929; called by muse, mutect2, varscan2
- MED12L | c.3814G>T p.E1272* | Nonsense Mutation (SNP) | VAF 49/150 reads (33%) | catalogued as COSV99853928; called by muse, mutect2, varscan2
- MED17 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 73/335 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs568876133, COSV52599249; called by muse, mutect2, varscan2
- MED23 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV63436948; called by muse, mutect2, varscan2
- MED23 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 91/338 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1267288026, COSV100644827, COSV100645221; called by muse, mutect2, varscan2
- MED7 | c.267C>A p.F89L | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1229627065, COSV53850102; called by muse, mutect2, varscan2
- METTL21A | c.382A>C p.N128H | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as COSV99777669; called by muse, mutect2
- MGAT4C | c.437C>A p.S146Y | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.581); catalogued as COSV100152770; called by muse, mutect2, varscan2
- MGAT4D | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.997); catalogued as rs1443774515; called by muse, mutect2
- MICU3 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 58/270 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.965); catalogued as rs200154899; called by muse, mutect2, varscan2
- MID1 | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 142/532 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs150291968, COSV58195523; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MINDY1 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 67/321 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs749897207, COSV56497289; called by muse, mutect2, varscan2
- MIS18BP1 | c.3178C>T p.R1060C | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs1162798560, COSV60370567; called by muse, mutect2, varscan2
- MNS1 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 97/400 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.423); catalogued as rs752613858, COSV53068388; called by muse, mutect2, varscan2
- MOCOS | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as rs141020986; called by muse, mutect2, varscan2
- MORC4 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55239939; called by muse, mutect2, varscan2
- MOV10 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 103/319 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62492691; called by muse, mutect2, varscan2
- MPP1 | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 52/196 reads (27%) | catalogued as COSV65728032; called by muse, varscan2
- MPPED1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.451); catalogued as rs779636377; called by muse, mutect2
- MRM1 | c.629T>G p.F210C | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1051745500; called by muse, mutect2, varscan2
- MRPS27 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 42/257 reads (16%) | catalogued as rs186771195; called by muse, mutect2, varscan2
- MRPS35 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as rs949842474; called by mutect2, varscan2
- MS4A14 | c.1375G>T p.D459Y | Missense Mutation (SNP) | VAF 88/309 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1468824967, COSV55734569, COSV55739606; called by muse, mutect2, varscan2
- MS4A2 | c.117G>T p.L39F | Missense Mutation (SNP) | VAF 118/456 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV54012122; called by muse, mutect2, varscan2
- MS4A4A | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1477195170; called by muse, mutect2, varscan2
- MTA1 | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV58755648; called by muse, mutect2, varscan2
- MTERF1 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV61098048, COSV61098955; called by muse, mutect2, varscan2
- MTF1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 88/319 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1269651707, COSV65990614; called by muse, mutect2, varscan2
- MTHFD2L | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs575932490, COSV57470302; called by muse, mutect2, varscan2
- MTIF2 | c.428C>T p.T143M | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs561472882, COSV55051891; called by muse, mutect2, varscan2
- MTMR10 | c.1963A>C p.K655Q | Missense Mutation (SNP) | VAF 101/379 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV58728123; called by muse, mutect2, varscan2
- MTMR9 | c.788G>A p.R263Q | Missense Mutation (SNP) | VAF 76/288 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs756683891; called by muse, mutect2, varscan2
- MTMR9 | c.1367C>A p.S456Y | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55314025; called by muse, mutect2, varscan2
- MTUS1 | c.2643G>T p.K881N (on ENST00000262102 / NM_001363061.1; = p.K47N on NM_020749.4) | Missense Mutation (SNP) | VAF 79/316 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373807625; called by muse, mutect2, varscan2
- MUC12 | c.16163C>T p.A5388V (on ENST00000379442; = p.A5245V on NM_001164462.1) | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.191); catalogued as rs755336618; called by muse, mutect2, varscan2
- MUC16 | c.20732C>A p.T6911N | Missense Mutation (SNP) | VAF 130/426 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs371481946; called by muse, mutect2, varscan2
- MUC17 | c.7865G>A p.S2622N | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs371470717, COSV100072216; called by muse, mutect2, varscan2
- MUC2 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 86/326 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs1325767468; called by muse, mutect2, varscan2
- MVD | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 113/405 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs780429715; called by muse, varscan2
- MYBPC1 | c.2662C>T p.R888C (on ENST00000550270 / NM_206820.2; = p.R895C on NM_002465.4) | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760890500, COSV62257120; called by muse, mutect2, varscan2
- MYCBP2 | c.12610C>T p.R4204C (on ENST00000357337; = p.R4242C on NM_015057.5) | Missense Mutation (SNP) | VAF 83/317 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1243730121, COSV62027741; called by muse, mutect2, varscan2
- MYCBP2 | c.11479C>T p.R3827* (on ENST00000357337; = p.R3865* on NM_015057.5) | Nonsense Mutation (SNP) | VAF 142/492 reads (29%) | catalogued as rs1258270536, COSV100630676, COSV62010851; called by muse, varscan2
- MYCBP2 | c.7282A>G p.N2428D (on ENST00000357337; = p.N2466D on NM_015057.5) | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs1346934110; called by muse, mutect2, varscan2
- MYH3 | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 103/358 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs747837966; called by muse, mutect2, varscan2
- MYH3 | c.4138G>A p.A1380T | Missense Mutation (SNP) | VAF 160/596 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.595); catalogued as COSV56862921; called by muse, varscan2
- MYH4 | c.4687C>A p.L1563I | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs371801767; called by mutect2, varscan2
- MYH8 | c.3142C>T p.R1048* | Nonsense Mutation (SNP) | VAF 111/361 reads (31%) | catalogued as rs977910326, COSV67960700; called by muse, mutect2, varscan2
- MYO15A | c.5761C>T p.R1921* | Nonsense Mutation (SNP) | VAF 110/367 reads (30%) | catalogued as rs760490445; called by muse, mutect2, varscan2
- MYO18B | c.4699G>A p.A1567T | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as COSV100122535, COSV59124365; called by muse, mutect2, varscan2
- MYO1E | c.3275G>A p.R1092Q | Missense Mutation (SNP) | VAF 151/516 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs749958731; called by muse, mutect2, varscan2
- MYO3A | c.1370G>T p.R457I | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV99779268; called by muse, mutect2, varscan2
- MYO3A | c.2898G>T p.E966D | Missense Mutation (SNP) | VAF 153/642 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as rs1369139226; called by muse, mutect2, varscan2
- MYO5B | c.3190C>T p.R1064* | Nonsense Mutation (SNP) | VAF 168/441 reads (38%) | catalogued as rs752799569, COSV99544018; called by muse, mutect2, varscan2
- MYO7B | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs200299859; called by muse, mutect2, varscan2
- MYO9A | c.3650G>A p.R1217Q | Missense Mutation (SNP) | VAF 120/445 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs193029114; called by muse, mutect2, varscan2
- MYO9A | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs754348944, COSV61857919; called by muse, mutect2, varscan2
- MYORG | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 183/640 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757434146, COSV52627943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- N4BP2L2 | c.2296C>A p.L766M (on ENST00000674422; = p.L337M on NM_033111.4) | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV62633192; called by muse, mutect2, varscan2
- NAA35 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV64484899; called by muse, mutect2, varscan2
- NAALAD2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs915139665, COSV58958529; called by muse, mutect2, varscan2
- NAALAD2 | c.490C>A p.L164I | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV100428435; called by muse, mutect2, varscan2
- NADK2 | c.1277C>T p.S426L (on ENST00000381937 / NM_001085411.3; = p.S263L on NM_153013.4) | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.146); catalogued as rs761705765; called by muse, mutect2, varscan2
- NAP1L3 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 86/290 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1316905621, COSV59078039; called by muse, mutect2, varscan2
- NAT14 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 69/287 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.365); catalogued as COSV99219839; called by muse, mutect2, varscan2
- NAT2 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 27/91 reads (30%) | catalogued as COSV54062477; called by muse, mutect2, varscan2
- NAT9 | c.393C>T p.Y131= | Splice Region (SNP) | VAF 92/333 reads (28%) | catalogued as rs370054214; called by muse, mutect2, varscan2
- NBEA | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 40/130 reads (31%) | catalogued as rs1296627050, COSV59785071; called by muse, mutect2, varscan2
- NBEAL2 | c.6806C>T p.S2269L | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749896920, CM116054; called by muse, mutect2, varscan2
- NBPF14 | c.2613A>C p.K871N | Missense Mutation (SNP) | VAF 134/1110 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1326098751; called by muse, mutect2, varscan2
- NCBP1 | c.990G>T p.K330N | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100912599; called by muse, mutect2, varscan2
- NCF4 | c.93G>T p.E31D | Missense Mutation (SNP) | VAF 197/729 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV50621159; called by muse, mutect2, varscan2
- NDC1 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs373565166; called by muse, mutect2, varscan2
- NDN | c.717C>A p.F239L | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59358887, COSV59359751; called by muse, mutect2, varscan2
- NDNF | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.819); catalogued as rs62325232, COSV101113147; called by muse, mutect2, varscan2
- NDST4 | c.1721A>G p.N574S | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.391); catalogued as rs911224162; called by muse, mutect2, varscan2
- NDUFAF4 | c.452C>A p.S151Y | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs201955429, COSV100294052; called by muse, mutect2, varscan2
- NEB | c.17806G>T p.E5936* | Nonsense Mutation (SNP) | VAF 55/227 reads (24%) | catalogued as rs1209865784, CM1413915; called by muse, mutect2, varscan2
- NEB | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs747423578, COSV50879612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEDD4 | c.3322C>A p.L1108I (on ENST00000508342 / NM_001284338.1; = p.L689I on NM_006154.4) | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as COSV59058405; called by muse, mutect2, varscan2
- NEDD4 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 54/171 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs746298752, COSV100163716; called by muse, mutect2, varscan2
- NEK10 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as rs201183358; called by muse, mutect2, varscan2
- NELL2 | c.1777T>G p.F593V | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.824); catalogued as COSV61581575; called by muse, mutect2, varscan2
- NEXMIF | c.3599C>T p.S1200F | Missense Mutation (SNP) | VAF 158/524 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV50117873; called by muse, mutect2, varscan2
- NF1 | c.2903T>G p.M968R | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as rs199474749, CM030257; ClinVar: not provided; called by muse, mutect2, varscan2
- NFASC | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 82/316 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as rs749105428; called by muse, mutect2, varscan2
- NFE2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.147); catalogued as rs368417462; called by muse, mutect2, varscan2
- NID2 | c.3166G>A p.G1056R | Missense Mutation (SNP) | VAF 95/399 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1318952059, COSV53500382; called by muse, mutect2, varscan2
- NIPAL1 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 99/396 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV99784325; called by muse, mutect2, varscan2
- NISCH | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 137/509 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.976); catalogued as rs745490517, COSV61900384; called by muse, mutect2, varscan2
- NKAPD1 | c.228G>T p.K76N | Missense Mutation (SNP) | VAF 114/403 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs1455715653, COSV54777891; called by muse, mutect2, varscan2
- NKTR | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs536150678, COSV51769497; called by muse, mutect2, varscan2
- NLRP9 | c.1023G>C p.W341C | Missense Mutation (SNP) | VAF 83/411 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs201446326; called by muse, mutect2, varscan2
- NME8 | c.1488T>G p.I496M | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs904540282; called by muse, mutect2, varscan2
- NOBOX | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs750447943, COSV56198164; called by muse, mutect2, varscan2
- NOL8 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 53/186 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.085); catalogued as rs940164063, COSV62634185; called by muse, mutect2, varscan2
- NOTCH1 | c.3880G>A p.E1294K | Missense Mutation (SNP) | VAF 231/815 reads (28%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.774); catalogued as rs1247035429, COSV53031178; called by muse, mutect2, varscan2
- NPAP1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs760531837; called by muse, mutect2, varscan2
- NPC1 | c.1094C>T p.S365L | Missense Mutation (SNP) | VAF 169/670 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.1); catalogued as rs200243024; called by muse, mutect2, varscan2
- NRAP | c.4351C>A p.P1451T (on ENST00000359988 / NM_001322945.2; = p.P1416T on NM_006175.4) | Missense Mutation (SNP) | VAF 77/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779945176; called by muse, mutect2, varscan2
- NRG3 | c.1329G>T p.M443I | Missense Mutation (SNP) | VAF 74/352 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs552349442, CM133994; called by muse, mutect2, varscan2
- NRXN1 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 116/491 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs756844822, COSV60486238; called by muse, mutect2, varscan2
- NRXN2 | c.3664G>A p.D1222N | Missense Mutation (SNP) | VAF 134/477 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55450970; called by muse, mutect2, varscan2
- NRXN3 | c.2135G>A p.R712H (on ENST00000335750 / NM_001330195.2; = p.R339H on NM_004796.6) | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766679074, COSV59735181, COSV99046672; called by muse, mutect2, varscan2
- NSF | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1350949739; called by mutect2, varscan2
- NUCB2 | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 43/176 reads (24%) | catalogued as rs767768972, COSV60375242; called by muse, mutect2, varscan2
- NUDT14 | c.428+1G>A p.X143_splice | Splice Site (SNP) | VAF 71/233 reads (30%) | catalogued as rs767363978; called by muse, mutect2, varscan2
- NUP210 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs758235896; called by muse, mutect2, varscan2
- NUP98 | c.4465C>T p.R1489* (on ENST00000359171 / NM_001365126.1; = p.R1472* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 104/414 reads (25%) | catalogued as COSV61428153; called by muse, mutect2, varscan2
- ODR4 | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.617); catalogued as rs773519415; called by muse, mutect2, varscan2
- OGT | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as rs267606503, COSV65479400, COSV65482451; called by muse, mutect2, varscan2
- OPRM1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1010052797, COSV100001511, COSV57674181; called by muse, mutect2, varscan2
- OR10D3 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 118/431 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as rs1379228083; called by muse, mutect2, varscan2
- OR10W1 | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV67720869; called by mutect2, varscan2
- OR10Z1 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as rs1367534054; called by muse, mutect2, varscan2
- OR11A1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1313503194; called by muse, mutect2, varscan2
- OR13G1 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 120/488 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs768400566, COSV62945569, COSV99069603; called by muse, mutect2, varscan2
- OR14A16 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.411); catalogued as COSV62926091, COSV62926585, COSV62927398; called by muse, mutect2, varscan2
- OR1D5 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 78/624 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV73859510; called by muse, mutect2, varscan2
- OR1K1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 81/249 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.872); catalogued as rs767407973, COSV52956062; called by muse, mutect2, varscan2
- OR2F2 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 34/105 reads (32%) | catalogued as COSV101283848, COSV68833068; called by mutect2, varscan2
- OR2L2 | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 63/305 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs775755002; called by muse, mutect2, varscan2
- OR2M5 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 165/683 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs374386978, COSV63545752; called by muse, mutect2, varscan2
- OR4K2 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs750303655; called by muse, mutect2, varscan2
- OR4L1 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.976); catalogued as COSV100235509; called by muse, mutect2, varscan2
- OR51E1 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 63/195 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs534822783, COSV67809714; called by muse, mutect2, varscan2
- OR52N5 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 85/269 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs372227128; called by muse, mutect2, varscan2
- OR5B3 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.577); catalogued as rs190645593, COSV58676470; called by muse, mutect2
- OR6C76 | c.436T>C p.W146R | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60390216; called by muse, mutect2, varscan2
- OR6P1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 133/460 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV58108194; called by muse, mutect2, varscan2
- OR7D2 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100713091; called by muse, mutect2, varscan2
- OR8J3 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100040808, COSV56879723; called by muse, mutect2
- OR8K1 | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); catalogued as COSV54405099; called by muse, mutect2, varscan2
- OR9G4 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 128/421 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs765828142, COSV57248357; called by muse, mutect2, varscan2
- OR9Q1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.541); catalogued as rs762002690; called by muse, varscan2
- OSBPL10 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as rs781373263; called by muse, mutect2, varscan2
- OSBPL6 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs775315470; called by muse, mutect2, varscan2
- OSGEPL1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs180971036; called by muse, mutect2, varscan2
- OTUD5 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 101/391 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1557055622, COSV99029067; called by muse, mutect2, varscan2
- OTUD6A | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 108/335 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV57973670; called by muse, mutect2, varscan2
- P2RY12 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 161/576 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs370954402, COSV56368739; called by muse, mutect2, varscan2
- P3H2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs752928706, COSV60024253; called by muse, varscan2
- PAFAH2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201993548, COSV65339805; called by muse, mutect2, varscan2
- PALD1 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 69/208 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs780268863; called by muse, mutect2, varscan2
- PAM | c.974C>A p.S325Y | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1023910255; called by muse, mutect2, varscan2
- PAN2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 72/296 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs780940788; called by muse, mutect2, varscan2
- PANX3 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs188711105, COSV52511231; called by muse, mutect2, varscan2
- PARG | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 79/342 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV67859921; called by muse, mutect2, varscan2
- PARP11 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.297); catalogued as COSV57393777, COSV57398210; called by muse, mutect2, varscan2
- PARP11 | c.312A>G p.I104M | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV57393744; called by muse, mutect2, varscan2
2,194 further variants in this file (1,313 protein-altering or splice-affecting, 543 silent, 338 other) are not listed here.
